Gene-level copy-number profile of tumor specimen ALCH-AEPG-TTP1-A from ALCHEMIST case ALCH-AEPG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.9 years (24,451 days).
Specimen ALCH-AEPG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d585b7b-aaf1-49b8-aece-1e2c35ea6b09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEPG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/4221a2e5-1d42-475a-808c-4c606a91e4e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 1,529; copy number 2: 54,870; copy number 3: 1,881; copy number 4: 19; copy number 5: 8; copy number 6: 1; copy number 8: 1; copy number 11: 2; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,699,456–143,699,619, 1 gene: RNVU1-17.
- chr2:120,319,007–120,351,803, 2 genes: AC012363.2, INHBB.
- chr2:132,285,795–132,294,377, 1 gene: AC097532.1.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr3:46,719,583–46,736,429, 1 gene (within-gene range 0–2): PRSS46P.
- chr5:99,522,311–99,534,611, 2 genes: AC114324.1, GUSBP8.
- chr7:129,756,266–129,785,185, 5 genes (within-gene range 0–2): RNA5SP244, MIR182, MIR96, MIR183, AC084864.1.
- chr9:79,135,374–79,198,314, 1 gene: AL512634.1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr12:132,351,855–132,352,322, 1 gene: AC148477.8.
- chr13:100,027,769–100,028,174, 1 gene: NDUFA12P1.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,828,095–41,852,029, 3 genes (within-gene range 0–2): JMJD7-PLA2G4B, PLA2G4B, RNA5SP393.
- chr15:73,335,260–73,342,387, 1 gene (within-gene range 0–1): AC068397.2.
- chr17:44,115,912–44,120,595, 1 gene (within-gene range 0–2): AC023855.1.
- chr17:75,588,058–75,626,849, 1 gene (within-gene range 0–1): MYO15B.
- chr18:46,667,821–46,802,449, 3 genes (within-gene range 0–2): ST8SIA5, AC090311.1, AC090241.2.
- chr19:38,184,376–38,200,934, 3 genes (within-gene range 0–2): AC011479.3, AC011479.2, RN7SL663P.
- chr20:23,125,068–23,132,635, 1 gene: LINC00656.
- chr20:47,826,969–47,827,044, 1 gene: RNU7-173P.
- chr21:44,347,767–44,348,295, 1 gene: AP001063.1.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,432,204–120,434,052, 1 gene, copy number 8: PFN1P2.
- chr6:166,305,300–166,308,448, 1 gene, copy number 6: PRR18.
- chr7:102,473,118–102,478,907, 1 gene, copy number 20 (within-gene range 2–20): POLR2J.
- chr16:1,612,337–1,702,280, 5 genes, copy number 5: CRAMP1, Z97652.1, AL031708.1, JPT2, AL031009.1.
- chr16:90,173,217–90,222,851, 1 gene, copy number 5 (within-gene range 2–5): LINC02193.
- chr22:18,846,811–18,894,407, 4 genes, copy number 5–11: AC008132.1, BCRP7, FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 1,320. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
